Somatic mutation profile of tumor specimen MP2PRT-PARLEE-TMP1-A (aliquot MP2PRT-PARLEE-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARLEE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,769 days).
Specimen MP2PRT-PARLEE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 620655f0-ad8b-4ae9-a19a-5fec9a3a5775.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLEE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLEE-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e674eb1-8ea1-4298-a6ed-5a081202afd4

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15088C>T p.R5030C | Missense Mutation (SNP) | VAF 150/551 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555185875, CM138453, COSV56417619; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 48/427 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AHNAK | c.3463G>A p.V1155I | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749813716, COSV57211895; called by muse, mutect2
- CSMD1 | c.8876G>A p.R2959H (on ENST00000520002; = p.R2958H on NM_033225.6) | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59313602; called by muse, mutect2, varscan2
- GRIN3B | c.1149G>A p.W383* | Nonsense Mutation (SNP) | VAF 50/787 reads (6%) | catalogued as rs1269869033; called by muse, mutect2
- HRNR | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 38/479 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs771199419, COSV64257627; called by muse, mutect2
- HTR3E | c.733C>T p.R245C (on ENST00000415389 / NM_001256613.1; = p.R260C on NM_182589.2) | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs781513210, COSV100093776; called by mutect2, varscan2
- LZTS1 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs771940536; called by muse, mutect2, varscan2
- NRXN1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 317/717 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs752126111, COSV68015645; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 160/382 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.10207C>T p.R3403W | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373251185; called by muse, mutect2
- SACM1L | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 103/257 reads (40%) | called by muse, mutect2, varscan2
- CELSR1 | c.6588C>G p.A2196= | Silent (SNP) | VAF 66/704 reads (9%) | catalogued as COSV99418879; called by muse, mutect2
- DENND10 | c.846A>G p.L282= | Silent (SNP) | VAF 140/498 reads (28%) | called by muse, mutect2, varscan2
- PLXNB1 | c.3465C>T p.H1155= | Silent (SNP) | VAF 90/340 reads (26%) | catalogued as rs751648829, COSV56490712; called by muse, mutect2, varscan2
- PRKG2 | c.1935G>A p.T645= | Silent (SNP) | VAF 84/219 reads (38%) | catalogued as COSV52332557; called by muse, mutect2, varscan2
- TARM1 | c.258C>T p.G86= (on ENST00000616041 / NM_001330650.1; = p.G78= on NM_001135686.3) | Silent (SNP) | VAF 32/775 reads (4%) | catalogued as rs751406924, COSV101444637, COSV71524728; called by muse, mutect2
- LRGUK | c.1843+8307C>T | Intron (SNP) | VAF 165/393 reads (42%) | catalogued as rs543279089; called by muse, mutect2, varscan2
